Surgical pathology report (de-identified scan), TCGA case TCGA-GN-A26D, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Roswell, specimen TCGA-GN-A26D-06A (Metastatic).

1CD-0-3

Melanoma, malignant, NOS 8720/3

Site: lymph nodes, iliac 0775 hr
4/27/11

SPECIMENS:

- A. LEFT ILIAC AND OBTURATOR LYMPH NODES
- B. LEFT INGUINAL LYMPH NODE

SPECIMEN(S):

- A. LEFT ILIAC AND OBTURATOR LYMPH NODES
- B. LEFT INGUINAL LYMPH NODE

GROSS DESCRIPTION:

A. LEFT ILIAC AND OBTURATOR LYMPH NODES

Received fresh are multiple tan pink soft tissue fragments aggregating to 7.6 x 6.8 x 4 cm. Dissection reveals eleven tan pink lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 5 x 4 x 3 cm. The largest lymph node is sectioned to reveal a necrotic hemorrhagic cut surface. A portion of the specimen is submitted for tissue procurement. The remaining lymph nodes are submitted as follows:

- A1: 5 lymph nodes
- A2: 1 lymph node
- A3: 2 lymph nodes
- A4: 1 lymph node
- A5-A6: 1 lymph node
- A7-A10: 3 lymph nodes

B. LEFT INGUINAL LYMPH NODE

Received in formalin is a tan pink firm lymph node 4.3 x 2.8 x 2.5 cm. The specimen is serially sectioned to reveal a homogenous necrotic cut surface. Representatively submitted in B1-B4.

DIAGNOSIS:

A. LYMPH NODES, LEFT ILIAC AND OBTURATOR, EXCISION:

- METASTATIC MELANOMA TO TWO OF NINE LYMPH NODES (2/9), WITH EXTRANODAL EXTENSION
- THE LARGEST METASTASIS IS 5.0 CM IN GREATEST DIMENSION

B. LYMPH NODE, LEFT INGUINAL, EXCISION:

- METASTATIC MELANOMA TO ONE LYMPH NODE (1/1), WITH EXTRANODAL EXTENSION
- THE METASTASIS IS 4.3 CM IN GREATEST DIMENSION

CLINICAL HISTORY:

None provided.

PRE-OPERATIVE DIAGNOSIS:

Melanoma in transit

Gross Dictation: .

Microscopic/Diagnostic Dictation: Pathologist.

Final Review: Pathologist.

Final: ., Pathologist.

IHC/AA Discrepancy		

Source: NCI Genomic Data Commons file 2f9c6204-e346-4080-9eee-626328dbd940 (TCGA-GN-A26D.BDAC6146-CB80-499E-A75F-B4A82FA56333.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).